Somatic mutation profile of tumor specimen TCGA-KO-8415-01A (aliquot TCGA-KO-8415-01A-11D-2310-10) from TCGA case TCGA-KO-8415, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 44.9 years (16,395 days).
Specimen TCGA-KO-8415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0175b78-1364-40af-bf20-075b9bad4904.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8415-11A (Solid Tissue Normal), aliquot TCGA-KO-8415-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf2a190e-8f95-49dd-9d28-f9ca05eafee7

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs59115483, CM021625, COSV99357931; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRA2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs144591273; called by muse, mutect2, varscan2
- ADGRV1 | c.6434G>A p.G2145E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67986683; called by muse, mutect2, varscan2
- ARSD | c.1245G>C p.M415I | Missense Mutation (SNP) | VAF 101/163 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99472078; called by muse, mutect2, varscan2
- CPPED1 | c.380A>T p.N127I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903005; called by muse, mutect2, varscan2
- CSMD1 | c.2236G>A p.V746M (on ENST00000520002; = p.V745M on NM_033225.6) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59341205; called by muse, mutect2, varscan2
- DGKA | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs751007578, COSV59383984; called by muse, mutect2, varscan2
- DSC3 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100844571; called by muse, mutect2, varscan2
- DYNC1I1 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100268043; called by muse, mutect2, varscan2
- EVL | c.701G>T p.R234I (on ENST00000402714 / NM_001330221.2; = p.R236I on NM_016337.3) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV101233061; called by muse, mutect2, varscan2
- FAM189B | c.259T>A p.W87R | Missense Mutation (SNP) | VAF 59/77 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100226673; called by muse, mutect2, varscan2
- ING1 | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.775); catalogued as rs1197272017, COSV100312077; called by muse, mutect2, varscan2
- KRT34 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.528); catalogued as rs777623549, COSV67450441; called by muse, mutect2, varscan2
- LCAT | c.806T>A p.I269K | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99862989; called by muse, mutect2, varscan2
- RANBP17 | c.3261G>A p.M1087I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV101206188; called by muse, mutect2, varscan2
- TG | c.8072G>A p.R2691H | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs531167775, COSV99600120; called by muse, mutect2, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 81/134 reads (60%) | called by mutect2, pindel, varscan2
- BRINP3 | c.1884C>T p.Y628= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100818624; called by muse, mutect2, varscan2
- GRIN2B | c.1080G>A p.P360= | Silent (SNP) | VAF 114/245 reads (47%) | catalogued as rs201952040, COSV74204867; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4M1 | c.279C>A p.S93= | Silent (SNP) | VAF 92/1413 reads (7%) | catalogued as COSV60062196, COSV60063846; called by muse, mutect2
- PCDHGA4 | c.1599C>T p.S533= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as COSV99535192, COSV99547627; called by muse, mutect2, varscan2
- SIN3B | c.2598G>A p.T866= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs766054809, COSV56136330; called by muse, mutect2, varscan2
- XDH | c.396C>T p.P132= | Silent (SNP) | VAF 70/91 reads (77%) | catalogued as rs761129062, COSV65148115; called by muse, mutect2, varscan2
- ZNF615 | c.186A>C p.R62= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as COSV100943752; called by muse, mutect2, varscan2
